Somatic mutation profile of tumor specimen C3L-08634-01 (aliquot CPT0481660009) from CPTAC case C3L-08634, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 48.7 years (17,787 days).
Specimen C3L-08634-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2806e48e-ec34-4b0d-9bd0-8a063e872ebf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08634-31 (Blood Derived Normal), aliquot CPT0481690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0623bd54-e0b6-432a-894b-a1c00ca0a06a

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 23, Nonsense Mutation 7, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM33 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 42/537 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769833760; called by muse, mutect2
- ADPRHL1 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.47); catalogued as rs932488754; called by muse, mutect2
- ANKRD2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs755630370, COSV100081053; called by muse, mutect2, varscan2
- APCDD1 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV100790037; called by muse, mutect2
- BMPR1B | c.1463A>C p.K488T | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52780457; called by muse, mutect2, varscan2
- CCDC69 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140977954; called by muse, mutect2
- DAOA | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs200951630, COSV61602376; called by muse, mutect2
- DCHS1 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs761187405, COSV55036733; called by muse, mutect2
- DCLK1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1340568626, COSV55173920; called by muse, mutect2
- DIP2C | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs952051588; called by muse, mutect2
- ELAVL1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 30/358 reads (8%) | catalogued as COSV60969153; called by muse, mutect2
- ETV6 | c.1253G>C p.R418T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765662; called by muse, mutect2
- IGBP1 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 65/453 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60555724; called by muse, mutect2, varscan2
- INTS6L | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143312165, COSV100878115; called by muse, mutect2
- JOSD2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs749166920, COSV67119090; called by muse, mutect2
- KCNS2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs780101812; called by muse, mutect2
- KLHL26 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs770299800; called by muse, mutect2, varscan2
- LGI1 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 37/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394822961, COSV65058066; called by muse, mutect2
- LIMCH1 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs562812091, COSV58285174; called by muse, mutect2
- LRP1B | c.4894C>T p.R1632* | Nonsense Mutation (SNP) | VAF 18/266 reads (7%) | catalogued as COSV67187956; called by muse, mutect2
- MAGEB18 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV57464221, COSV57465130; called by muse, mutect2, varscan2
- MFGE8 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 31/292 reads (11%) | catalogued as rs141213799, COSV51555726; called by muse, mutect2
- MTG1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 27/550 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs767632663; called by muse, mutect2
- MYOM3 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs200017159; called by muse, mutect2
- NYAP2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 51/548 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs551352616, COSV55999744; called by muse, mutect2
- OR4A8 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs920969449; called by muse, mutect2
- P2RY6 | c.567T>A p.Y189* | Nonsense Mutation (SNP) | VAF 34/584 reads (6%) | catalogued as COSV100574014; called by muse, mutect2
- PCDH10 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs770920439, COSV52096283; called by muse, mutect2
- PCDH19 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 37/704 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55260143; called by muse, mutect2
- PLEKHG4B | c.1567G>T p.E523* (on ENST00000283426; = p.E879* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 25/355 reads (7%) | catalogued as COSV52054997; called by muse, mutect2
- PPP6R2 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204791894; called by muse, mutect2
- RYR2 | c.9743G>A p.R3248H | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1041429670; ClinVar: uncertain significance; called by muse, mutect2
- SCD | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752736513; called by muse, mutect2
- SLCO1A2 | c.1583C>A p.A528D | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs531004465; called by muse, mutect2
- TANC2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV67343879; called by muse, mutect2
- TBC1D24 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs767293945, COSV53546586; ClinVar: uncertain significance; called by muse, mutect2
- TLL1 | c.1636A>G p.R546G | Missense Mutation (SNP) | VAF 27/380 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV50261406, COSV99286343; called by muse, mutect2
- TRIML1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); catalogued as rs1306667910; called by muse, mutect2
- TTN | c.91775G>A p.R30592Q (on ENST00000591111; = p.R23168Q on NM_003319.4) | Missense Mutation (SNP) | VAF 27/366 reads (7%) | PolyPhen probably damaging (0.992); catalogued as rs755082341, COSV100618376; ClinVar: uncertain significance; called by muse, mutect2
- UGT2B11 | c.367T>G p.F123V | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs748002147; called by muse, mutect2, varscan2
- ZNF219 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 48/547 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1156340731, COSV53881861; called by muse, mutect2
- ZNF536 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 42/481 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868633299, COSV62832754, COSV62837289; called by muse, mutect2
- ZNF735 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV70035784; called by muse, mutect2
- ADGRV1 | c.13645G>A p.E4549K | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2
- AP3D1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2
- AXIN2 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CABP7 | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); called by muse, mutect2
- CCDC136 | c.2642T>C p.M881T | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHD4 | c.2681A>G p.N894S (on ENST00000357008 / NM_001363606.2; = p.N907S on NM_001273.5) | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DSCAM | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, mutect2
- EZHIP | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 40/517 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- FAM47A | c.1974G>A p.M658I | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FBXO30 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- GRIN2A | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- HIP1R | c.2233C>G p.L745V | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- KIF26A | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 57/602 reads (9%) | called by muse, mutect2
- LRP12 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- LRRN3 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- MED24 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 15/499 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- MRAP2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- MUC16 | c.26173A>T p.R8725* | Nonsense Mutation (SNP) | VAF 40/509 reads (8%) | called by muse, mutect2
- PTEN | c.154_155dup p.D52Efs*3 | Frame Shift Ins (INS) | VAF 22/220 reads (10%) | called by mutect2, pindel
- RREB1 | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 27/577 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- RXFP4 | c.41T>C p.F14S | Missense Mutation (SNP) | VAF 29/350 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- SAAL1 | c.433_436del p.L145Mfs*56 | Frame Shift Del (DEL) | VAF 29/226 reads (13%) | called by mutect2, pindel, varscan2
- SEZ6L | c.2380A>G p.S794G | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZSWIM8 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP2B2 | c.2715C>T p.I905= (on ENST00000352432; = p.I871= on NM_001683.5) | Silent (SNP) | VAF 27/321 reads (8%) | catalogued as rs1268337252, COSV59506069; called by muse, mutect2
- DNAH2 | c.7338C>T p.S2446= | Silent (SNP) | VAF 13/224 reads (6%) | catalogued as rs532707394, COSV66720238; called by muse, mutect2
- DTHD1 | c.1725C>T p.N575= (on ENST00000456874; = p.N410= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as rs555041609, COSV62630205; called by muse, mutect2
- FAM71B | c.1125G>A p.A375= | Silent (SNP) | VAF 35/484 reads (7%) | catalogued as rs777781639, COSV57229393; called by muse, mutect2
- GPR27 | c.417C>T p.C139= | Silent (SNP) | VAF 45/518 reads (9%) | called by muse, mutect2
- GRID1 | c.1893C>T p.R631= | Silent (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- ILDR2 | c.1812C>G p.S604= | Silent (SNP) | VAF 39/441 reads (9%) | called by muse, mutect2
- ITGB7 | c.2247G>A p.S749= | Silent (SNP) | VAF 35/360 reads (10%) | catalogued as rs771753910, COSV57239259; called by muse, mutect2, varscan2
- KCNN2 | c.468G>A p.S156= (on ENST00000264773; = p.S368= on NM_021614.4) | Silent (SNP) | VAF 25/301 reads (8%) | catalogued as COSV53284002; called by muse, mutect2
- NBEAL2 | c.5256G>A p.G1752= | Silent (SNP) | VAF 37/384 reads (10%) | called by muse, mutect2
- NPTX2 | c.864C>T p.P288= | Silent (SNP) | VAF 26/362 reads (7%) | catalogued as rs1464132127, COSV55718458; called by muse, mutect2
- OR2A14 | c.324C>T p.H108= | Silent (SNP) | VAF 42/323 reads (13%) | catalogued as rs559068119, COSV68718415, COSV68718571; called by muse, mutect2, varscan2
- PLXNB1 | c.6096G>A p.P2032= | Silent (SNP) | VAF 22/274 reads (8%) | catalogued as rs755753973, COSV56488586; called by muse, mutect2
- PPP1R42 | c.108A>T p.S36= | Silent (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- RASGRP2 | c.447G>A p.L149= | Silent (SNP) | VAF 25/327 reads (8%) | called by muse, mutect2
- RYR3 | c.12312C>T p.S4104= (on ENST00000389232; = p.S4105= on NM_001036.6) | Silent (SNP) | VAF 20/422 reads (5%) | catalogued as rs1192127709, COSV66801973; called by muse, mutect2
- SCN1A | c.2700C>T p.I900= (on ENST00000303395 / NM_001202435.3; = p.I889= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as rs747722810, COSV57684061; called by muse, mutect2
- SCN3A | c.4533A>G p.P1511= | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- TSKS | c.1122C>T p.R374= | Silent (SNP) | VAF 28/480 reads (6%) | catalogued as rs542983208, COSV55873870; called by muse, mutect2
- VEGFA | c.192G>A p.E64= (on ENST00000523873 / NM_001171623.1; = p.E244= on NM_003376.6) | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as COSV57880127; called by muse, mutect2
- ZBTB37 | c.639G>A p.R213= | Silent (SNP) | VAF 25/458 reads (5%) | called by muse, mutect2
- ZNF521 | c.1971C>A p.L657= | Silent (SNP) | VAF 28/406 reads (7%) | catalogued as COSV100832705; called by muse, mutect2
- ZNF667 | c.1335C>T p.C445= | Silent (SNP) | VAF 21/300 reads (7%) | called by muse, mutect2
- ZNF677 | c.169+1881G>A | Intron (SNP) | VAF 17/289 reads (6%) | catalogued as rs369096628; called by muse, mutect2
